Somatic mutation profile of tumor specimen C3N-03781-01 (aliquot CPT0245550006) from CPTAC case C3N-03781, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 68.2 years (24,899 days).
Specimen C3N-03781-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7db980cf-4864-497c-88cb-5708bd00bfea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03781-31 (Blood Derived Normal), aliquot CPT0245590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31ea1cb9-7a50-4061-b4c9-be343281b502

The open-access MAF lists 238 somatic variants for this specimen: 154 protein-altering or splice-affecting, 47 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 47, Intron 20, Nonsense Mutation 17, 5'UTR 7, RNA 5, 5'Flank 3, Frame Shift Ins 3, Splice Site 2, Frame Shift Del 2, 3'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 83/305 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1328G>T p.R443I | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs917987175, COSV70044468; called by muse, mutect2, varscan2
- ACSL6 | c.1205G>A p.R402Q (on ENST00000379240; = p.R427Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/407 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs762139509, COSV57297152; called by muse, mutect2, varscan2
- ACTN2 | c.2572C>G p.Q858E | Missense Mutation (SNP) | VAF 97/519 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV63973423; called by muse, mutect2, varscan2
- AGBL5 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs766150855; called by muse, mutect2, varscan2
- AHNAK | c.14723C>T p.S4908L | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs146517943; called by muse, mutect2, varscan2
- ALPK2 | c.6499G>A p.E2167K | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs543965909, COSV64492583, COSV64495347; called by muse, mutect2, varscan2
- ANK3 | c.10627G>C p.D3543H | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1179851287; called by muse, mutect2, varscan2
- ARAP1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs1023068303; called by muse, mutect2, varscan2
- ASCC1 | c.433C>T p.R145* (on ENST00000342444 / NM_001369085.1; = p.R117* on NM_001198798.2 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 62/547 reads (11%) | catalogued as rs746994660; called by muse, mutect2, varscan2
- ATP10A | c.4394G>C p.G1465A | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.285); catalogued as rs765333392; called by muse, mutect2
- CACNB2 | c.1531C>T p.R511C (on ENST00000324631 / NM_201596.3; = p.R456C on NM_000724.4) | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs764111314, COSV56620175; called by muse, mutect2, varscan2
- CLMN | c.1816G>C p.G606R | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.741); catalogued as rs200712769; called by muse, mutect2, varscan2
- EFR3A | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs369535816; called by muse, mutect2, varscan2
- ENGASE | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100285594; called by muse, mutect2, varscan2
- EP400 | c.3872G>A p.R1291H | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs761082851, COSV57764103; called by muse, mutect2, varscan2
- EPHA6 | c.1969G>A p.V657I (on ENST00000389672 / NM_001080448.3; = p.V49I on NM_173655.4) | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs753848380, COSV67592998; called by muse, mutect2, varscan2
- FBLN2 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 128/489 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434436621, COSV99852971; called by muse, mutect2, varscan2
- FH | c.1347G>A p.M449I | Missense Mutation (SNP) | VAF 76/466 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as rs376502356, CD020860, COSV99053231; called by muse, varscan2
- FMN2 | c.4454C>A p.P1485Q | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV60444464; called by muse, mutect2, varscan2
- FOXC1 | c.1019C>G p.S340W | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66516754; called by muse, mutect2, varscan2
- GAD2 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1406817819; called by muse, mutect2, varscan2
- GANAB | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs769911576; called by muse, mutect2, varscan2
- GPS2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 36/257 reads (14%) | catalogued as COSV59747879; called by muse, mutect2, varscan2
- HIVEP2 | c.6300G>A p.M2100I | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs759420075; called by muse, mutect2, varscan2
- IFNA4 | c.527C>G p.S176W | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV70180202; called by muse, mutect2, varscan2
- IGHV4-39 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as rs750441991; called by muse, mutect2, varscan2
- IL18BP | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.257); catalogued as rs771647889; called by muse, mutect2, varscan2
- IPO9 | c.1806A>C p.E602D | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV100843340; called by muse, mutect2, varscan2
- KAT6B | c.4021G>A p.E1341K | Missense Mutation (SNP) | VAF 81/482 reads (17%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as rs1282806882; called by muse, mutect2, varscan2
- KCNC3 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 79/448 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs750349505, COSV100979271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCLAT1 | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.997); catalogued as COSV100474720, COSV58373053; called by muse, mutect2, varscan2
- MED12L | c.2650G>A p.V884M | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1380964632; called by muse, mutect2, varscan2
- MYO15A | c.3742C>T p.R1248W | Missense Mutation (SNP) | VAF 78/578 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1171337671, COSV52765215; called by muse, mutect2, varscan2
- NDN | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167282078; called by muse, mutect2, varscan2
- OBSCN | c.12505G>A p.E4169K | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV52772064; called by muse, mutect2, varscan2
- OR4K2 | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1218850688, COSV53850086; called by muse, mutect2, varscan2
- OR51G1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775482982, COSV58968393; called by muse, mutect2, varscan2
- PLCXD3 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs757112105, COSV100125467, COSV60606218; called by muse, mutect2, varscan2
- POLQ | c.6127del p.R2043Dfs*15 | Frame Shift Del (DEL) | VAF 45/308 reads (15%) | catalogued as COSV51746339; called by mutect2, pindel, varscan2
- PPL | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 116/763 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs759068790; called by muse, mutect2, varscan2
- PPM1D | c.1641G>A p.M547I | Missense Mutation (SNP) | VAF 148/459 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs1383306871; called by muse, mutect2, varscan2
- PPP1R37 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs931840664; called by muse, mutect2, varscan2
- PTPRB | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54250067; called by muse, mutect2
- RC3H2 | c.1789C>G p.Q597E | Missense Mutation (SNP) | VAF 70/339 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV61801866; called by muse, mutect2, varscan2
- SH3KBP1 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101115053; called by muse, mutect2, varscan2
- SHANK1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1360502788; called by muse, mutect2, varscan2
- SHCBP1L | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 79/417 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); catalogued as COSV62355936; called by muse, mutect2, varscan2
- SLC25A52 | c.604G>A p.G202S (on ENST00000672005; = p.G192S on NM_001034172.4) | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as COSV52503641; called by muse, mutect2, varscan2
- SMG6 | c.1948C>G p.Q650E | Missense Mutation (SNP) | VAF 73/436 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99558141; called by muse, mutect2, varscan2
- SPEN | c.2279C>G p.S760* | Nonsense Mutation (SNP) | VAF 73/278 reads (26%) | catalogued as COSV101005256; called by muse, mutect2, varscan2
- TAS1R3 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 57/372 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs141557900; called by muse, mutect2, varscan2
- TGFBR2 | c.1547C>A p.T516K | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM085738; called by muse, mutect2, varscan2
- TMPRSS9 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs750216653; called by muse, mutect2, varscan2
- TRIM59 | c.-74+7C>T | Splice Region (SNP) | VAF 38/296 reads (13%) | catalogued as rs751221152; called by muse, mutect2, varscan2
- TRPC3 | c.571G>A p.V191I (on ENST00000379645 / NM_001366479.2; = p.V118I on NM_003305.2) | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53374304; called by muse, mutect2, varscan2
- TSKS | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV55873311; called by muse, mutect2, varscan2
- UGT2B11 | c.430A>T p.R144* | Nonsense Mutation (SNP) | VAF 40/304 reads (13%) | catalogued as COSV71424315; called by muse, mutect2, varscan2
- ZGRF1 | c.4534G>C p.E1512Q | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV58342721; called by muse, mutect2, varscan2
- ZNF180 | c.1864C>G p.Q622E | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.615); catalogued as COSV99659793; called by muse, mutect2, varscan2
- ZNF429 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs202050037; called by muse, mutect2, varscan2
- AC127029.3 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 227/660 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ACTN4 | c.1922A>C p.Q641P | Missense Mutation (SNP) | VAF 158/865 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADSL | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 60/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AJUBA | c.769del p.A257Rfs*8 | Frame Shift Del (DEL) | VAF 102/413 reads (25%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.4966C>G p.L1656V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); called by muse, varscan2
- ANKRD20A1 | c.1938G>C p.M646I | Missense Mutation (SNP) | VAF 68/988 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2
- AXIN1 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 67/623 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- BAIAP3 | c.3155T>A p.V1052E | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- BPIFA3 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BTBD7 | c.1899C>A p.S633R | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- BTBD9 | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 45/436 reads (10%) | called by muse, mutect2, varscan2
- BTN3A3 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 76/557 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- C20orf144 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 88/574 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.161); called by mutect2, varscan2
- CAMK2A | c.1075G>A p.E359K (on ENST00000348628 / NM_171825.2; = p.E370K on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH24 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 67/519 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CEP250 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CEP295 | c.7763delinsCAT p.H2588Pfs*6 | Frame Shift Ins (INS) | VAF 26/128 reads (20%) | called by pindel, varscan2*
- CERCAM | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- COL20A1 | c.2839G>C p.D947H | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2
- CUL5 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHPS | c.870dup p.A291Cfs*23 | Frame Shift Ins (INS) | VAF 34/236 reads (14%) | called by mutect2, pindel, varscan2
- DMBT1 | c.911C>G p.S304* | Nonsense Mutation (SNP) | VAF 106/698 reads (15%) | called by muse, varscan2
- DPRX | c.96C>G p.N32K | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DSCAM | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- EML2 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 70/506 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FAM20B | c.577A>G p.N193D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.258); called by muse, mutect2
- FREM3 | c.1817C>G p.S606* | Nonsense Mutation (SNP) | VAF 39/209 reads (19%) | called by muse, mutect2, varscan2
- GNPAT | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 75/457 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- GRAMD1B | c.1229-1G>C p.X410_splice | Splice Site (SNP) | VAF 15/116 reads (13%) | called by muse, varscan2
- H3C12 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- HABP2 | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HACE1 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ICE2 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.1); called by muse, mutect2
- ING1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM6B | c.3591C>G p.F1197L | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KIAA2012 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- LANCL2 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- LCLAT1 | c.1023G>T p.R341S | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LDB2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- LONP1 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAN1C1 | c.1859C>G p.S620* | Nonsense Mutation (SNP) | VAF 63/263 reads (24%) | called by muse, mutect2, varscan2
- MAP2 | c.3988G>C p.E1330Q | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED23 | c.2030C>G p.S677* | Nonsense Mutation (SNP) | VAF 33/270 reads (12%) | called by muse, mutect2, varscan2
- MFSD2B | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MORN1 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MYO3A | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYOM1 | c.4240C>A p.L1414I | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- MYRF | c.581C>T p.P194L (on ENST00000278836 / NM_001127392.3; = p.P185L on NM_013279.4) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- NFXL1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NR4A3 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NYX | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OLFML2B | c.2052T>G p.Y684* | Nonsense Mutation (SNP) | VAF 65/409 reads (16%) | called by muse, mutect2, varscan2
- OR5I1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PACS1 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 112/662 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PCBP2 | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- PER1 | c.2941C>G p.P981A | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PHIP | c.3976G>T p.E1326* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.659A>C p.Q220P | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- POU3F4 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP1R13L | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- PPP1R16B | c.1196A>T p.N399I | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- PRMT9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 38/385 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PRUNE2 | c.5341G>A p.A1781T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPN3 | c.1198G>C p.A400P | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- RASGEF1A | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASGEF1A | c.291G>C p.Q97H | Missense Mutation (SNP) | VAF 47/447 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2
- RAVER2 | c.1588C>T p.Q530* (on ENST00000294428 / NM_001366165.1; = p.Q517* on NM_018211.4) | Nonsense Mutation (SNP) | VAF 90/417 reads (22%) | called by muse, mutect2, varscan2
- RBM45 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RELB | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RICTOR | c.2623C>G p.H875D | Missense Mutation (SNP) | VAF 53/233 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIPK1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ROBO3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- RYR2 | c.4850G>A p.W1617* | Nonsense Mutation (SNP) | VAF 39/300 reads (13%) | called by muse, mutect2, varscan2
- SCN3B | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 93/638 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SELENOT | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SLC13A4 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- SLC4A1 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 195/589 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SNAP91 | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SOSTDC1 | c.517_519del p.N173del | In Frame Del (DEL) | VAF 44/406 reads (11%) | called by mutect2, pindel, varscan2
- SPART | c.1905G>T p.Q635H | Missense Mutation (SNP) | VAF 61/309 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SPATA31D1 | c.4518G>C p.K1506N | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SRBD1 | c.2055C>G p.D685E | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- STON1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX5 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 93/603 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD15 | c.1435G>C p.E479Q | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- TPBGL | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); called by muse, mutect2
- TTN | c.84155A>G p.Q28052R (on ENST00000591111; = p.Q20628R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TYW5 | c.79-1G>C p.X27_splice | Splice Site (SNP) | VAF 34/207 reads (16%) | called by muse, mutect2, varscan2
- UBA6 | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ZNF2 | c.904C>G p.Q302E (on ENST00000611147 / NM_001291605.2; = p.Q289E on NM_021088.4) | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF471 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ZNF750 | c.676_677dup p.G227Rfs*140 | Frame Shift Ins (INS) | VAF 107/410 reads (26%) | called by mutect2, pindel, varscan2
- AADACL4 | c.996C>A p.V332= | Silent (SNP) | VAF 55/428 reads (13%) | catalogued as COSV66106758; called by muse, mutect2, varscan2
- ABCF1 | c.783G>A p.L261= | Silent (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- ACACB | c.2277C>A p.L759= | Silent (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- ACSF2 | c.969G>C p.L323= | Silent (SNP) | VAF 78/308 reads (25%) | called by muse, mutect2, varscan2
- ADNP2 | c.450C>T p.S150= | Silent (SNP) | VAF 27/193 reads (14%) | catalogued as rs770107576; called by muse, mutect2, varscan2
- AGRN | c.3006C>T p.G1002= | Silent (SNP) | VAF 19/158 reads (12%) | catalogued as rs774744948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B4 | c.2695C>T p.L899= | Silent (SNP) | VAF 70/534 reads (13%) | called by muse, mutect2, varscan2
- CASQ1 | c.1068C>T p.S356= | Silent (SNP) | VAF 57/298 reads (19%) | catalogued as rs188615821, COSV63623553; called by muse, mutect2, varscan2
- CDH3 | c.1230G>T p.V410= | Silent (SNP) | VAF 96/722 reads (13%) | called by muse, mutect2, varscan2
- CFAP221 | c.1506G>A p.S502= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as rs371319201, COSV54653891; called by muse, mutect2, varscan2
- DCHS2 | c.615C>A p.T205= | Silent (SNP) | VAF 57/469 reads (12%) | catalogued as COSV59741316; called by muse, mutect2, varscan2
- DDX25 | c.828C>G p.L276= | Silent (SNP) | VAF 27/199 reads (14%) | called by muse, mutect2, varscan2
- DRC7 | c.78G>A p.A26= | Silent (SNP) | VAF 46/260 reads (18%) | catalogued as rs999382151; called by muse, varscan2
- DUSP6 | c.15C>T p.L5= | Silent (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2
- EED | c.1212G>T p.L404= | Silent (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- EEF1E1 | c.210C>A p.I70= | Silent (SNP) | VAF 67/454 reads (15%) | catalogued as COSV65675575; called by muse, mutect2, varscan2
- ERN1 | c.1563G>A p.S521= | Silent (SNP) | VAF 89/217 reads (41%) | catalogued as rs758467855, COSV101458374; called by muse, mutect2, varscan2
- ESCO1 | c.2244C>T p.V748= | Silent (SNP) | VAF 38/215 reads (18%) | called by muse, mutect2, varscan2
- ESPL1 | c.4296G>C p.L1432= | Silent (SNP) | VAF 56/325 reads (17%) | called by muse, mutect2, varscan2
- G6PD | c.1107G>A p.V369= | Silent (SNP) | VAF 73/261 reads (28%) | called by muse, mutect2, varscan2
- GZMM | c.255C>T p.D85= | Silent (SNP) | VAF 42/326 reads (13%) | called by muse, mutect2, varscan2
- HAS3 | c.1170C>T p.P390= | Silent (SNP) | VAF 65/507 reads (13%) | catalogued as rs201342230; called by muse, mutect2, varscan2
- HDAC9 | c.1584G>A p.R528= | Silent (SNP) | VAF 60/484 reads (12%) | called by muse, mutect2, varscan2
- HYDIN | c.5904C>G p.V1968= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as rs376492054; called by muse, mutect2
- IL1RAPL2 | c.1245T>C p.T415= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100780640, COSV100781340; called by muse, mutect2
- KIAA0100 | c.291G>A p.T97= | Silent (SNP) | VAF 43/328 reads (13%) | catalogued as rs139655833; called by muse, mutect2, varscan2
- KIRREL2 | c.855G>A p.L285= | Silent (SNP) | VAF 74/382 reads (19%) | called by muse, mutect2, varscan2
- LCAT | c.102G>A p.P34= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs919086282, CD098959; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.4446C>G p.V1482= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV67202834; called by muse, mutect2
- LRRC71 | c.1671C>T p.F557= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs781205488; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1038C>T p.L346= | Silent (SNP) | VAF 35/269 reads (13%) | catalogued as rs926014404; called by muse, mutect2, varscan2
- MPRIP | c.1068C>G p.L356= | Silent (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1803C>T p.N601= | Silent (SNP) | VAF 160/568 reads (28%) | catalogued as COSV53940091; called by muse, mutect2, varscan2
- PCSK4 | c.1980C>T p.R660= | Silent (SNP) | VAF 71/416 reads (17%) | catalogued as rs756704922; called by muse, mutect2, varscan2
- PLXNB3 | c.1101G>A p.S367= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs558515318, COSV62799683; called by muse, mutect2, varscan2
- PSD3 | c.2758C>T p.L920= (on ENST00000440756; = p.L919= on NM_015310.4) | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as rs377209838, COSV54067396; called by muse, mutect2, varscan2
- SIX1 | c.264G>A p.L88= | Silent (SNP) | VAF 59/416 reads (14%) | called by muse, mutect2, varscan2
- SLA | c.9C>T p.N3= (on ENST00000338087 / NM_001045556.3; = p.N43= on NM_006748.4) | Silent (SNP) | VAF 24/145 reads (17%) | called by muse, mutect2, varscan2
- SLC35F1 | c.39G>A p.P13= | Silent (SNP) | VAF 76/486 reads (16%) | called by muse, mutect2, varscan2
- SLC39A4 | c.771C>T p.I257= (on ENST00000301305 / NM_001374839.1; = p.I232= on NM_017767.3) | Silent (SNP) | VAF 102/603 reads (17%) | catalogued as rs1554873347; called by muse, mutect2, varscan2
- SLCO3A1 | c.1527T>C p.C509= | Silent (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2
- SNAP91 | c.189C>G p.L63= | Silent (SNP) | VAF 34/330 reads (10%) | catalogued as rs369939656; called by muse, mutect2, varscan2
- SNX5 | c.1083G>C p.L361= | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- TNFAIP1 | c.159C>G p.L53= | Silent (SNP) | VAF 33/240 reads (14%) | called by muse, mutect2, varscan2
- XPO5 | c.2469C>G p.L823= | Silent (SNP) | VAF 36/315 reads (11%) | called by muse, mutect2, varscan2
- ZNF483 | c.2202C>T p.L734= | Silent (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- ZSCAN12 | c.132C>G p.V44= | Silent (SNP) | VAF 42/282 reads (15%) | called by muse, mutect2, varscan2
- AC018638.4 | n.152C>G | RNA (SNP) | VAF 168/926 reads (18%) | called by muse, varscan2
- AC018638.4 | n.247C>T | RNA (SNP) | VAF 103/907 reads (11%) | catalogued as rs1454876491; called by muse, varscan2
- AC024598.1 | c.1130-900C>A | Intron (SNP) | VAF 62/454 reads (14%) | called by muse, mutect2, varscan2
- AC244258.1 | n.803C>A | RNA (SNP) | VAF 22/175 reads (13%) | catalogued as rs756467372; called by muse, varscan2
- ASMT | c.-23G>A | 5'UTR (SNP) | VAF 80/530 reads (15%) | catalogued as rs376891503; called by muse, mutect2, varscan2
- C4orf3 | chr4:119300726 C>G | 5'Flank (SNP) | VAF 8/74 reads (11%) | catalogued as rs1197511187; called by muse, varscan2
- CASK | c.831+27C>G | Intron (SNP) | VAF 76/235 reads (32%) | called by muse, mutect2, varscan2
- CLK2P1 | n.1105G>T | RNA (SNP) | VAF 84/553 reads (15%) | catalogued as rs768813092; called by muse, mutect2, varscan2
- DCDC1 | c.1221+26259T>A | Intron (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- FAM53C | chr5:138338111 G>A | 5'Flank (SNP) | VAF 60/263 reads (23%) | called by muse, mutect2, varscan2
- GALNT9 | c.1077+7253A>T | Intron (SNP) | VAF 64/634 reads (10%) | called by muse, mutect2
- GALNT9 | c.1077+7252G>T | Intron (SNP) | VAF 65/621 reads (10%) | catalogued as rs1458129816; called by muse, mutect2
- GOLGA4 | c.-50_-45delinsG | 5'UTR (DEL) | VAF 57/244 reads (23%) | called by pindel, varscan2*
- HNF1A | c.1309+196C>G | Intron (SNP) | VAF 57/260 reads (22%) | called by muse, mutect2, varscan2
- IKBKE | c.812+38G>C | Intron (SNP) | VAF 30/159 reads (19%) | called by muse, mutect2, varscan2
- IRF7 | c.223-24C>A | Intron (SNP) | VAF 26/95 reads (27%) | catalogued as rs1203182389; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847228 A>C | 5'Flank (SNP) | VAF 54/431 reads (13%) | called by muse, mutect2, varscan2
- MBNL1 | c.174+40172G>C | Intron (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- MDGA2 | c.281-41528G>A | Intron (SNP) | VAF 42/135 reads (31%) | catalogued as rs1016176372; called by muse, mutect2, varscan2
- MIR146A | n.62G>C | RNA (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- NAE1 | c.54-1278G>A | Intron (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.835-34G>A | Intron (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- NELFA | c.416-616G>A | Intron (SNP) | VAF 57/372 reads (15%) | called by muse, mutect2, varscan2
- NR5A1 | c.-7C>T | 5'UTR (SNP) | VAF 96/553 reads (17%) | catalogued as rs989611741; called by muse, mutect2, varscan2
- NUTM2D | c.-64G>A | 5'UTR (SNP) | VAF 105/1441 reads (7%) | called by muse, mutect2
- PARP14 | c.-10G>A | 5'UTR (SNP) | VAF 35/215 reads (16%) | catalogued as rs772029631; called by muse, mutect2, varscan2
- PMP22 | c.*32C>T | 3'UTR (SNP) | VAF 66/343 reads (19%) | catalogued as rs763703270, COSV56601293; called by muse, mutect2, varscan2
- PPA2 | c.157+253G>A | Intron (SNP) | VAF 29/281 reads (10%) | catalogued as rs1384664534; called by muse, mutect2, varscan2
- PROCR | c.*30G>C | 3'UTR (SNP) | VAF 50/301 reads (17%) | catalogued as rs757532803; called by muse, mutect2, varscan2
- PTPRK | c.100+1135G>A | Intron (SNP) | VAF 55/314 reads (18%) | called by muse, mutect2, varscan2
- SART3 | c.1723+39C>G | Intron (SNP) | VAF 52/391 reads (13%) | called by muse, mutect2, varscan2
- SHOC2 | c.-235+17570C>T | Intron (SNP) | VAF 38/297 reads (13%) | catalogued as rs1490135968; called by muse, mutect2, varscan2
- SORD | c.67-4076T>C | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- SPDYE4 | c.-28G>A | 5'UTR (SNP) | VAF 21/192 reads (11%) | called by muse, mutect2, varscan2
- TWF1 | c.25+116C>G | Intron (SNP) | VAF 61/412 reads (15%) | catalogued as rs779032546; called by muse, mutect2, varscan2
- UGP2 | c.1315-34G>A | Intron (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ZNF677 | c.-23G>C | 5'UTR (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
